Somatic mutation profile of tumor specimen C3L-07541-02 (aliquot CPT0477330006) from CPTAC case C3L-07541, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 79.2 years (28,939 days).
Specimen C3L-07541-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 888641ca-84bc-4c70-b9c4-92c6512898b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07541-31 (Blood Derived Normal), aliquot CPT0475600006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8da45a2-626d-4894-8c33-1888d2fad360

The open-access MAF lists 85 somatic variants for this specimen: 62 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 22, Nonsense Mutation 2, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD33 | c.649G>A p.V217M (on ENST00000340970 / NM_001304459.2; = p.V342M on NM_182608.4) | Missense Mutation (SNP) | VAF 75/604 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771237309, COSV56604895; called by muse, mutect2, varscan2
- ANKRD50 | c.3866G>A p.S1289N | Missense Mutation (SNP) | VAF 35/355 reads (10%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs765620183; called by muse, mutect2, varscan2
- AP2A1 | c.2455G>A p.G819S | Missense Mutation (SNP) | VAF 39/572 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.574); catalogued as rs773315954; called by muse, mutect2
- CACNA1B | c.5036G>A p.C1679Y | Missense Mutation (SNP) | VAF 99/489 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53153726; called by muse, mutect2, varscan2
- CCNB3 | c.3884A>G p.Y1295C | Missense Mutation (SNP) | VAF 38/656 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs200314516; called by muse, mutect2
- COBL | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 46/536 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs202232985, COSV54336910; called by muse, mutect2
- COL7A1 | c.7037G>A p.R2346H | Missense Mutation (SNP) | VAF 68/453 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs201432371, COSV60392298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD1 | c.3155C>T p.P1052L (on ENST00000520002; = p.P1051L on NM_033225.6) | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1388594836; called by muse, mutect2
- ERN2 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99892124; called by muse, mutect2
- EXT2 | c.1372G>T p.A458S (on ENST00000343631; = p.A491S on NM_000401.3) | Missense Mutation (SNP) | VAF 32/447 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146086025; called by muse, mutect2
- GRINA | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 15/450 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782544244; called by muse, mutect2
- HERC2 | c.13135G>A p.G4379R | Missense Mutation (SNP) | VAF 18/606 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs777881619; called by muse, mutect2
- HIVEP3 | c.2537A>C p.K846T | Missense Mutation (SNP) | VAF 31/538 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV56010537; called by muse, mutect2
- KATNIP | c.3014C>T p.P1005L | Missense Mutation (SNP) | VAF 42/466 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as rs777648421, COSV55174372; called by muse, mutect2
- KMT2A | c.6370C>T p.R2124* | Nonsense Mutation (SNP) | VAF 46/486 reads (9%) | catalogued as CM1511940, COSV63283453; called by muse, mutect2
- LAMC3 | c.4421C>T p.S1474L | Missense Mutation (SNP) | VAF 18/406 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs1321188909; called by muse, mutect2
- LATS2 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 51/891 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.893); catalogued as rs747638434, COSV66875845; called by muse, mutect2
- LCT | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 62/517 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs761976129, COSV51546823; called by muse, mutect2, varscan2
- MAGEB3 | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 48/581 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV64397113; called by muse, mutect2
- MAP7D2 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 50/401 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs774928077, COSV101107277, COSV65530773, COSV65530919; called by muse, mutect2, varscan2
- MIA3 | c.4309G>A p.G1437R | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749199420; called by muse, mutect2, varscan2
- NAV1 | c.2056G>A p.G686S | Missense Mutation (SNP) | VAF 32/583 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as rs772204331, COSV55215377; called by muse, mutect2
- OBSCN | c.20669G>A p.G6890E | Missense Mutation (SNP) | VAF 54/942 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs775665045; called by muse, mutect2
- OCLN | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 31/438 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1205714674; called by muse, mutect2
- OR5M8 | c.193T>G p.L65V | Missense Mutation (SNP) | VAF 30/596 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59116733; called by muse, mutect2
- PCDH17 | c.2879C>A p.A960E | Missense Mutation (SNP) | VAF 36/482 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.111); catalogued as COSV64976957; called by muse, mutect2
- PCDHA5 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 36/780 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.949); catalogued as rs1554129036, COSV65359481; called by muse, mutect2
- PTCH1 | c.1855G>A p.V619I | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.363); catalogued as rs1060502266, COSV59468306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIPK4 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 52/494 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1236858466, COSV60189920; called by muse, mutect2, varscan2
- SLC4A2 | c.3130G>A p.G1044S | Missense Mutation (SNP) | VAF 28/636 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV52540208; called by muse, mutect2
- SULF1 | c.889T>C p.Y297H | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1245322596; called by muse, mutect2
- TEX47 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 22/440 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs141995683; called by muse, mutect2
- B4GAT1 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 46/505 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2
- CCDC39 | c.1522C>A p.L508I | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- CDKL5 | c.1700C>T p.T567M | Missense Mutation (SNP) | VAF 52/517 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- CELSR1 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 36/652 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2
- CLEC16A | c.2850C>G p.D950E | Missense Mutation (SNP) | VAF 15/378 reads (4%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2
- COL14A1 | c.3683C>T p.A1228V | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- EHHADH | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 44/505 reads (9%) | called by muse, mutect2
- FAM114A1 | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- GPRASP1 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 25/669 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.108); called by muse, mutect2
- INHBE | c.257C>A p.P86Q | Missense Mutation (SNP) | VAF 48/435 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IPO11 | c.809T>C p.I270T | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2
- IREB2 | c.2422T>C p.F808L | Missense Mutation (SNP) | VAF 36/412 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); called by muse, mutect2
- KCNT1 | c.3648G>T p.K1216N (on ENST00000488444; = p.K1221N on NM_020822.3) | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); called by muse, mutect2
- MED23 | c.2401G>A p.D801N | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.615); called by muse, mutect2
- NECTIN1 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 48/583 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2
- NKX6-3 | c.679G>A p.E227K (on ENST00000518699 / NM_001364841.2; = p.E97K on NM_152568.3) | Missense Mutation (SNP) | VAF 40/862 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2
- NRP1 | c.518G>C p.C173S | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR6F1 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 32/610 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- PCDHB15 | c.1715G>T p.C572F | Missense Mutation (SNP) | VAF 36/808 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); called by muse, mutect2
- RAD50 | c.3476A>T p.D1159V | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNX8 | c.1062G>T p.R354S | Missense Mutation (SNP) | VAF 32/677 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2
- ST18 | c.1838C>T p.T613I | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM185A | c.865C>G p.L289V | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- TPR | c.4876G>C p.E1626Q | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- UNC13A | c.2076C>A p.D692E | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- UNC5D | c.2071C>A p.L691M | Missense Mutation (SNP) | VAF 26/662 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- WASHC5 | c.2309G>T p.W770L | Missense Mutation (SNP) | VAF 23/415 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZMPSTE24 | c.922G>C p.G308R | Missense Mutation (SNP) | VAF 29/340 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- ZNF236 | c.4093G>T p.A1365S | Missense Mutation (SNP) | VAF 21/537 reads (4%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.656); called by muse, mutect2
- ZNF287 | c.1751C>A p.T584N | Missense Mutation (SNP) | VAF 16/508 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); called by muse, mutect2
- BRINP1 | c.1870C>A p.R624= | Silent (SNP) | VAF 28/542 reads (5%) | called by muse, mutect2
- CNOT1 | c.3681A>G p.K1227= | Silent (SNP) | VAF 18/360 reads (5%) | called by muse, mutect2
- COL20A1 | c.3027G>A p.T1009= | Silent (SNP) | VAF 117/663 reads (18%) | catalogued as rs368035015; called by muse, mutect2, varscan2
- ELMO1 | c.1002T>G p.A334= | Silent (SNP) | VAF 16/392 reads (4%) | called by muse, mutect2
- FAM205A | c.318C>A p.I106= | Silent (SNP) | VAF 23/535 reads (4%) | called by muse, mutect2
- GIPC3 | c.684G>T p.G228= | Silent (SNP) | VAF 40/432 reads (9%) | catalogued as rs750168561; called by muse, mutect2, varscan2
- LPXN | c.642C>T p.C214= | Silent (SNP) | VAF 32/401 reads (8%) | catalogued as rs763418056, COSV67717190; called by muse, mutect2
- MAP2K5 | c.378C>T p.A126= | Silent (SNP) | VAF 41/428 reads (10%) | catalogued as rs370376340; called by muse, mutect2
- NAP1L3 | c.966T>G p.V322= | Silent (SNP) | VAF 18/538 reads (3%) | called by muse, mutect2
- NSUN7 | c.1086C>T p.H362= | Silent (SNP) | VAF 21/343 reads (6%) | called by muse, mutect2
- POLA1 | c.1449C>T p.S483= | Silent (SNP) | VAF 19/452 reads (4%) | called by muse, mutect2
- ROS1 | c.498C>T p.F166= | Silent (SNP) | VAF 18/528 reads (3%) | called by muse, mutect2
- RTN1 | c.1557G>A p.P519= | Silent (SNP) | VAF 62/723 reads (9%) | catalogued as rs763202784, COSV50718692; called by muse, mutect2
- SAMD9 | c.1296G>A p.K432= | Silent (SNP) | VAF 31/387 reads (8%) | called by muse, mutect2
- SHANK1 | c.3594C>A p.P1198= | Silent (SNP) | VAF 66/623 reads (11%) | called by muse, varscan2
- SLC12A5 | c.3390C>T p.G1130= (on ENST00000454036 / NM_001134771.2; = p.G1107= on NM_020708.5) | Silent (SNP) | VAF 22/446 reads (5%) | catalogued as rs1413192522; called by muse, mutect2
- SPSB4 | c.279C>T p.H93= | Silent (SNP) | VAF 82/666 reads (12%) | catalogued as rs1282300954, COSV60151120; called by muse, mutect2, varscan2
- TNC | c.1488C>T p.C496= | Silent (SNP) | VAF 67/648 reads (10%) | catalogued as COSV60785484; called by muse, mutect2, varscan2
- TOR4A | c.1080C>T p.I360= | Silent (SNP) | VAF 32/787 reads (4%) | catalogued as rs778932365, COSV62626580, COSV62627733; called by muse, mutect2
- TRAPPC9 | c.825C>T p.T275= | Silent (SNP) | VAF 16/446 reads (4%) | called by muse, mutect2
- WDR13 | c.633C>A p.R211= | Silent (SNP) | VAF 68/684 reads (10%) | catalogued as rs375330976, COSV54330909; called by muse, varscan2
- ZNF668 | c.1257C>T p.A419= | Silent (SNP) | VAF 103/599 reads (17%) | catalogued as rs149874277; called by muse, mutect2, varscan2
- PABPC1P4 | n.191G>T | RNA (SNP) | VAF 27/496 reads (5%) | called by muse, mutect2
